Somatic mutation profile of tumor specimen TCGA-A6-2671-01A (aliquot TCGA-A6-2671-01A-01D-1408-10) from TCGA case TCGA-A6-2671, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 85.8 years (31,329 days).
Specimen TCGA-A6-2671-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6efb189-e343-43de-9d81-1be7718a86b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2671-10A (Blood Derived Normal), aliquot TCGA-A6-2671-10A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5baac8a7-4918-4e39-a51a-29f796fcc2d3

The open-access MAF lists 95 somatic variants for this specimen: 60 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 34, Frame Shift Del 6, Nonsense Mutation 2, In Frame Del 2, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.7364G>T p.R2455L (on ENST00000614293; = p.R2425L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV55799530; called by muse, mutect2, varscan2
- ABCG1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV59202357; called by muse, mutect2, varscan2
- ADAM11 | c.1552G>C p.G518R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99567565; called by muse, mutect2, varscan2
- ADAM32 | c.2160C>T p.S720= | Splice Region (SNP) | VAF 17/114 reads (15%) | catalogued as rs372708183; called by muse, mutect2, varscan2
- AMER3 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs549719246, COSV58465897; called by muse, mutect2, varscan2
- AMER3 | c.2281G>A p.G761R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762936709, COSV58465900, COSV58470726; called by muse, mutect2, varscan2
- BACH2 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.414); catalogued as rs749061519, COSV57588447; called by muse, mutect2, varscan2
- BICDL2 | c.1031C>G p.P344R | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); catalogued as COSV54155854; called by muse, mutect2, varscan2
- C11orf42 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445285453, COSV56410485; called by muse, mutect2, varscan2
- C3orf20 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.039); catalogued as rs766458955, COSV53783738; called by muse, mutect2, varscan2
- CACNA1H | c.6209G>A p.R2070H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs777897759, COSV52353458; called by muse, mutect2, varscan2
- COL12A1 | c.1534T>G p.Y512D | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59392589; called by muse, mutect2, varscan2
- CRB1 | c.4217T>C p.I1406T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV66338624; called by muse, mutect2, varscan2
- DNAH8 | c.3760G>A p.G1254S | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59435123; called by muse, mutect2, varscan2
- EZHIP | c.1118G>C p.G373A | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV100539774; called by muse, mutect2, varscan2
- FBXO2 | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.182); catalogued as COSV99278994; called by mutect2, varscan2
- FLYWCH1 | c.1033_1035del p.E345del (on ENST00000253928 / NM_001308068.2; = p.E344del on NM_020912.1 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 22/37 reads (59%) | catalogued as rs767735750; called by mutect2, pindel, varscan2
- GABRB3 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs771568810, COSV100159362, COSV100160423; ClinVar: uncertain significance; called by muse, mutect2
- GML | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 24/220 reads (11%) | catalogued as rs1249379550, COSV55276774; called by muse, mutect2, varscan2
- GRIK2 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV59725067; called by muse, mutect2, varscan2
- HRNR | c.6082A>G p.S2028G | Missense Mutation (SNP) | VAF 60/581 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100913597; called by muse, mutect2, varscan2
- IFNA5 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.353); catalogued as COSV52386704; called by muse, mutect2, varscan2
- IL15RA | c.677G>A p.C226Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV66092485; called by muse, mutect2, varscan2
- LRBA | c.7064C>G p.S2355C | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63952376; called by muse, mutect2, varscan2
- LRR1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777495090, COSV53562554; called by muse, mutect2, varscan2
- MAP2 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs148723167; called by muse, mutect2, varscan2
- MMP9 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.516); catalogued as COSV64884527; called by muse, mutect2, varscan2
- MTMR11 | c.1821G>C p.W607C (on ENST00000439741 / NM_001145862.2; = p.W535C on NM_181873.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV54964249, COSV54964785; called by muse, mutect2
- MYBL1 | c.1489G>T p.G497C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101576552; called by muse, mutect2
- OR2T35 | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as rs780714893, COSV58085767; called by muse, mutect2, varscan2
- PBRM1 | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV56260223, COSV56261335; called by muse, mutect2, varscan2
- PC | c.2830G>A p.V944M | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747039077, COSV58992372; called by muse, mutect2, varscan2
- PCDHB4 | c.2122G>A p.V708M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV52021159; called by muse, mutect2, varscan2
- PCDHB7 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV50765127; called by muse, mutect2
- PCDHGA7 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53921174; called by muse, mutect2, varscan2
- PDE4A | c.1134C>A p.N378K (on ENST00000380702 / NM_001111307.2; = p.N139K on NM_006202.3) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV53352662; called by muse, mutect2, varscan2
- PLA2G3 | c.574T>C p.S192P | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV53208578; called by muse, mutect2, varscan2
- PLEKHG4B | c.713G>A p.R238H (on ENST00000283426; = p.R594H on NM_052909.5) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as rs777970072, COSV52045489; called by muse, mutect2, varscan2
- PLXNA4 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149257060, COSV58103872, COSV58133382; called by muse, mutect2, varscan2
- POGLUT2 | c.980C>A p.P327Q | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65682882; called by muse, mutect2, varscan2
- POTEH | c.397del p.S133Afs*71 | Frame Shift Del (DEL) | VAF 58/234 reads (25%) | catalogued as COSV58881580; called by mutect2, pindel, varscan2
- PPP1R12A | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.887); catalogued as COSV54107024; called by muse, mutect2, varscan2
- PSD2 | c.920G>T p.C307F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.363); catalogued as rs748747630, COSV51198026, COSV99216978; called by muse, mutect2, varscan2
- RBBP7 | c.1015C>A p.R339S | Missense Mutation (SNP) | VAF 58/78 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV58112665; called by muse, mutect2, varscan2
- RNF43 | c.1885del p.A629Pfs*71 | Frame Shift Del (DEL) | VAF 41/92 reads (45%) | catalogued as COSV68457261, COSV68457531; called by mutect2, pindel, varscan2
- SCN1A | c.1659C>A p.H553Q | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as COSV57665368; called by muse, mutect2, varscan2
- SCN3A | c.1718G>A p.S573N | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51805933; called by muse, mutect2, varscan2
- SLC25A32 | c.727T>A p.Y243N | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99884489; called by muse, mutect2
- SYNE1 | c.9318A>C p.K3106N (on ENST00000367255 / NM_182961.4; = p.K3113N on NM_033071.3) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54943581; called by muse, mutect2, varscan2
- TECPR1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776939148, COSV65782964; called by muse, mutect2, varscan2
- TMEM132B | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 77/99 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as rs767342934, COSV54749305; called by muse, mutect2, varscan2
- TWIST1 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM020324, CM099811, COSV54250389; called by muse, mutect2, varscan2
- U2SURP | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV67530427; called by muse, mutect2, varscan2
- ZNF831 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1179775792, COSV64038734; called by muse, varscan2
- APC | c.2827del p.S943Qfs*12 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- APC | c.4303_4324del p.R1435Lfs*31 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | called by mutect2, pindel, varscan2
- FN1 | c.332_335del p.T111Mfs*8 | Frame Shift Del (DEL) | VAF 33/77 reads (43%) | called by mutect2, pindel, varscan2
- KMT2C | c.13053dup p.W4352Mfs*17 | Frame Shift Ins (INS) | VAF 58/127 reads (46%) | called by mutect2, pindel, varscan2
- LAMA3 | c.7608_7610del p.V2537del (on ENST00000313654 / NM_198129.4; = p.V928del on NM_000227.6) | In Frame Del (DEL) | VAF 29/56 reads (52%) | called by pindel, varscan2
- TP53 | c.518_519del p.V173Efs*7 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by pindel, varscan2
- AC127029.3 | c.675T>G p.S225= | Silent (SNP) | VAF 40/59 reads (68%) | catalogued as rs763501141, COSV60110590; called by muse, mutect2, varscan2
- ACSF2 | c.165C>T p.I55= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs140242443; called by muse, mutect2, varscan2
- ACTRT2 | c.204C>A p.A68= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV65759096; called by muse, mutect2, varscan2
- ADCY2 | c.1782C>A p.A594= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV57865864, COSV57877157; called by muse, mutect2, varscan2
- ATP13A2 | c.3135C>T p.Y1045= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs766447629, COSV58699417; called by muse, mutect2, varscan2
- BMP10 | c.378C>T p.Y126= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV54894673; called by muse, mutect2, varscan2
- CCDC34 | c.720A>G p.L240= | Silent (SNP) | VAF 227/364 reads (62%) | catalogued as COSV60820423; called by muse, mutect2, varscan2
- CNGB3 | c.48G>A p.E16= | Silent (SNP) | VAF 78/503 reads (16%) | catalogued as COSV60687314; called by muse, mutect2, varscan2
- CRPPA | c.721T>C p.L241= (on ENST00000407010 / NM_001368197.1; = p.L191= on NM_001101417.4) | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV67905124; called by muse, mutect2, varscan2
- CTNNA2 | c.2817G>A p.S939= (on ENST00000402739 / NM_001282597.3; = p.S891= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs529719349, COSV100559150, COSV58143856; called by muse, mutect2, varscan2
- DCHS1 | c.2782C>A p.R928= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV55033171; called by muse, mutect2, varscan2
- DNAH2 | c.10290C>T p.H3430= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs749033023, COSV66718119; called by muse, mutect2, varscan2
- DSCAM | c.1788G>A p.P596= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs200014864; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM160A2 | c.1293C>T p.H431= | Silent (SNP) | VAF 90/147 reads (61%) | catalogued as rs368609593; called by muse, mutect2, varscan2
- FAT1 | c.4302A>G p.G1434= | Silent (SNP) | VAF 57/159 reads (36%) | catalogued as COSV101499413; called by muse, mutect2, varscan2
- FAT3 | c.4848C>A p.I1616= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV53093048, COSV99967055; called by muse, mutect2, varscan2
- FCGBP | c.6885C>T p.D2295= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as rs773651497; called by muse, mutect2, varscan2
- GJA3 | c.1080G>A p.P360= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99576415; called by muse, varscan2
- HDAC9 | c.1740G>A p.T580= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV67766560; called by muse, mutect2, varscan2
- HEG1 | c.3570C>A p.I1190= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV60760787; called by muse, mutect2, varscan2
- HEPACAM | c.315C>T p.G105= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV53429385, COSV53432303; called by muse, mutect2, varscan2
- KIF4B | c.2625C>A p.V875= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV70528557, COSV70530213; called by muse, mutect2, varscan2
- KRT34 | c.372G>A p.A124= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs761821120, COSV67449534; called by muse, mutect2, varscan2
- LGI4 | c.417C>A p.L139= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV59533117, COSV59533266; called by muse, mutect2, varscan2
- METTL24 | c.603C>T p.N201= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs200971763; called by muse, mutect2, varscan2
- PCDHB3 | c.267A>G p.K89= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV50567307; called by muse, mutect2, varscan2
- PLD2 | c.964C>A p.R322= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs757264558, COSV54004763; called by muse, mutect2
- RSPH1 | c.693G>A p.T231= | Silent (SNP) | VAF 70/125 reads (56%) | catalogued as rs372338741; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIN3A | c.138G>A p.E46= | Silent (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- SLC25A2 | c.873G>A p.R291= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV53403384; called by muse, mutect2, varscan2
- ST3GAL1 | c.843C>T p.C281= | Silent (SNP) | VAF 65/74 reads (88%) | catalogued as rs764268995, COSV60611525; called by muse, mutect2
- SYNM | c.3015C>G p.V1005= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV50441199; called by muse, mutect2, varscan2
- ZIC1 | c.327C>T p.D109= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99292062; called by muse, mutect2, varscan2
- ZNF831 | c.1638G>A p.S546= | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as rs562181302, COSV64038740; called by muse, mutect2, varscan2
- TTN | c.10361-4758G>T | Intron (SNP) | VAF 62/165 reads (38%) | catalogued as COSV100626894, COSV59964319, COSV60047407; called by muse, mutect2, varscan2
